Somatic mutation profile of tumor specimen TCGA-CV-7413-01A (aliquot TCGA-CV-7413-01A-11D-2078-08) from TCGA case TCGA-CV-7413, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 74.6 years (27,231 days).
Specimen TCGA-CV-7413-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6444ba07-46da-455c-bcdf-6f8b62bd3af3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7413-10A (Blood Derived Normal), aliquot TCGA-CV-7413-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3e6aded-cf20-4de0-9558-b18f5de1e632

The open-access MAF lists 80 somatic variants for this specimen: 61 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 18, Nonsense Mutation 3, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 33/72 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ACSBG1 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as rs1170809449, COSV51905004; called by muse, mutect2, varscan2
- ADAM28 | c.2240C>G p.S747C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV56097911, COSV99738134; called by muse, mutect2, varscan2
- ADAMTS17 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs539824002, COSV51477551; called by muse, mutect2, varscan2
- AFF2 | c.3289G>A p.V1097M | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99662610; called by muse, mutect2, varscan2
- AFF4 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363866725, COSV99534704; called by muse, mutect2, varscan2
- AGBL1 | c.3250C>G p.H1084D | Missense Mutation (SNP) | VAF 47/163 reads (29%) | PolyPhen benign (0.001); catalogued as COSV101222405; called by muse, mutect2, varscan2
- APOLD1 | c.609_611del p.F204del (on ENST00000326765 / NM_001130415.2; = p.F173del on NM_030817.3) | In Frame Del (DEL) | VAF 40/161 reads (25%) | catalogued as rs761796342; called by pindel, varscan2
- ARHGAP27 | c.2518C>T p.R840C (on ENST00000428638 / NM_001282290.1; = p.R499C on NM_199282.3) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100976470; called by muse, mutect2
- ARHGEF10L | c.3707G>T p.C1236F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV99392265; called by muse, mutect2, varscan2
- AXL | c.2024C>A p.A675D (on ENST00000301178 / NM_021913.5; = p.A666D on NM_001699.6) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99996158; called by muse, mutect2, varscan2
- BRF2 | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99604799; called by mutect2, varscan2
- CARM1 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100498910; called by muse, mutect2, varscan2
- CASP8 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51856633; called by muse, mutect2, varscan2
- CCDC107 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100526197; called by muse, mutect2, varscan2
- CLEC9A | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs746971143, COSV63350641; called by muse, mutect2, varscan2
- CYB5R1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV100924825; called by muse, mutect2, varscan2
- DISP3 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53822232; called by muse, mutect2
- DOCK8 | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs750025996, COSV101209841; called by muse, mutect2
- DSEL | c.1943A>T p.D648V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403056217, COSV100025384; called by muse, mutect2, varscan2
- FAT1 | c.4429C>T p.Q1477* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV71674630; called by muse, mutect2, varscan2
- GALNT2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100795542, COSV64195990; called by muse, mutect2, varscan2
- GPBP1 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1345886063, COSV53312520, COSV99302559; called by muse, mutect2, varscan2
- GRM8 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV100281510; called by muse, mutect2, varscan2
- H1-5 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV100137765, COSV58901828; called by muse, mutect2, varscan2
- HBG2 | c.325A>T p.N109Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100400586; called by muse, mutect2, varscan2
- HPS6 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.494); catalogued as COSV100154812; called by muse, mutect2, varscan2
- KCNQ3 | c.2537C>T p.T846M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765623435, COSV66477046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIR2DL3 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 56/505 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.062); catalogued as rs1247801082, COSV99399791; called by muse, varscan2
- KPNA6 | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101012454; called by muse, mutect2, varscan2
- KRT79 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV100398332; called by muse, mutect2, varscan2
- LRBA | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV100841107; called by muse, mutect2, varscan2
- LRP1 | c.6617G>T p.R2206L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV54503511, COSV54514106; called by muse, mutect2, varscan2
- LRP1B | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101254175; called by muse, mutect2, varscan2
- MAEL | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.152); catalogued as rs773190752, COSV63305334; called by muse, mutect2, varscan2
- NFATC2 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101043780; called by muse, mutect2, varscan2
- NT5C1B | c.1388G>A p.R463H (on ENST00000359846 / NM_001199086.2; = p.R403H on NM_033253.4) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201567504, COSV58397396; called by muse, mutect2, varscan2
- OR4C15 | c.702G>T p.L234F (on ENST00000314644; = p.L180F on NM_001001920.2) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.386); catalogued as COSV100115462; called by muse, mutect2, varscan2
- PAF1 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99655653; called by muse, mutect2, varscan2
- PCDHB13 | c.2029G>C p.A677P | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV53399918, COSV99506968; called by muse, mutect2, varscan2
- PCDHB2 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.113); catalogued as COSV99164387; called by muse, mutect2, varscan2
- PSMB7 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99412737; called by mutect2, varscan2
- RAI1 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99883619; called by muse, mutect2, varscan2
- RASA1 | c.2812C>T p.Q938* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99169665; called by muse, mutect2, varscan2
- RASAL2 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100862495; called by muse, mutect2, varscan2
- RBM12B | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as COSV101234487; called by muse, mutect2, varscan2
- RIMBP2 | c.2914G>A p.V972I | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs142858015; called by muse, mutect2, varscan2
- RNF128 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.579); catalogued as COSV100176030; called by muse, mutect2, varscan2
- SAMD15 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.035); catalogued as COSV53628468; called by muse, mutect2, varscan2
- SEC61A2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1479543999, COSV100036292; called by muse, mutect2
- SIRT3 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV100291433; called by muse, mutect2
- SORCS3 | c.1288T>C p.Y430H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100864791; called by muse, mutect2, varscan2
- TAOK2 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV99664130; called by muse, mutect2, varscan2
- TENM2 | c.5860G>A p.E1954K (on ENST00000518659 / NM_001122679.2; = p.E1715K on NM_001080428.3) | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV101318226, COSV69129914; called by muse, mutect2, varscan2
- THAP11 | c.263G>C p.R88P | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV99534298; called by mutect2, varscan2
- TIPARP | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55815067; called by muse, mutect2, varscan2
- TOR4A | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.2); PolyPhen benign (0.2); catalogued as COSV100677668; called by muse, mutect2, varscan2
- ZCCHC13 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV100272478; called by muse, mutect2, varscan2
- ZNF189 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.136); catalogued as COSV99407124; called by muse, mutect2, varscan2
- MORC4 | c.532dup p.M178Nfs*23 | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- ACSM4 | c.735C>T p.S245= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV101257070; called by muse, mutect2, varscan2
- ADGRV1 | c.5088C>A p.I1696= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV101315629; called by muse, mutect2, varscan2
- CELF2 | c.1494G>A p.L498= (on ENST00000416382 / NM_001025077.3; = p.L511= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100257006; called by muse, mutect2, varscan2
- FAT4 | c.9690G>C p.V3230= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100627690; called by muse, mutect2, varscan2
- H4C6 | c.60C>T p.R20= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100897480; called by muse, mutect2, varscan2
- KANK2 | c.2334C>T p.C778= (on ENST00000586659 / NM_001379562.1; = p.C786= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs774676609, COSV100763080; called by muse, mutect2, varscan2
- KRTAP6-3 | c.332G>A p.*111= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101196472; called by muse, mutect2
- LFNG | c.198C>T p.Y66= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs199923575, COSV101273403; called by mutect2, varscan2
- NHS | c.1857G>A p.T619= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs767954983, COSV101196461; called by muse, mutect2, varscan2
- NLRP7 | c.1695G>C p.V565= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100051915; called by muse, mutect2, varscan2
- OAS2 | c.1533A>G p.K511= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV100660038; called by muse, mutect2, varscan2
- OR6C4 | c.672G>T p.L224= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV101263136; called by muse, mutect2, varscan2
- PDXDC1 | c.1920G>A p.Q640= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as COSV99816822; called by muse, mutect2, varscan2
- STYXL2 | c.1512G>A p.A504= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1488666216, COSV54806491; called by muse, mutect2, varscan2
- TCTE1 | c.525G>A p.A175= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs754460257, COSV65255345; called by muse, mutect2, varscan2
- TRIO | c.7509G>C p.P2503= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100702480; called by muse, mutect2, varscan2
- UBE4B | c.3888G>A p.E1296= (on ENST00000343090 / NM_001105562.3; = p.E1167= on NM_006048.5) | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV53543663; called by muse, mutect2, varscan2
- VWA3B | c.3237C>T p.S1079= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV101289413; called by muse, mutect2, varscan2
- ACAA2 | chr18:49814195 C>T | 5'Flank (SNP) | VAF 14/106 reads (13%) | catalogued as rs1017500307; called by muse, mutect2, varscan2
